Somatic mutation profile of tumor specimen TCGA-V1-A8MF-01A (aliquot TCGA-V1-A8MF-01A-11D-A364-08) from TCGA case TCGA-V1-A8MF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland.
Specimen TCGA-V1-A8MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb82c314-b309-4ce8-9218-e9ee84b1983b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V1-A8MF-10A (Blood Derived Normal), aliquot TCGA-V1-A8MF-10A-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7048c182-ded9-43cd-9389-d9c3516e9656

The open-access MAF lists 27 somatic variants for this specimen: 24 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Nonsense Mutation 3, Silent 2, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCG4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs746685392, COSV56642005, COSV56643302; called by muse, mutect2
- ANAPC4 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV100194022; called by muse, mutect2, varscan2
- BCL11A | c.1274C>T p.A425V (on ENST00000335712 / NM_001365609.1; = p.A459V on NM_018014.4) | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100185729, COSV59634982; called by mutect2, varscan2
- CD5L | c.233T>A p.L78* | Nonsense Mutation (SNP) | VAF 21/176 reads (12%) | catalogued as COSV100941052; called by muse, mutect2, varscan2
- COL4A4 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); catalogued as rs774801022, COSV100306922; called by muse, mutect2, varscan2
- G6PC2 | c.175T>C p.W59R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as rs369755574; called by muse, mutect2, varscan2
- HDAC10 | c.1598dup p.K534Qfs*40 | Frame Shift Ins (INS) | VAF 18/85 reads (21%) | catalogued as rs1435922527; called by mutect2, pindel, varscan2
- LINGO2 | c.1793C>A p.P598H | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100430591; called by muse, mutect2, varscan2
- LRP1B | c.6532G>T p.D2178Y | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV101257510, COSV67270444; called by muse, mutect2, varscan2
- LTBP2 | c.2647G>A p.A883T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.78); PolyPhen benign (0.034); catalogued as COSV100000377; called by muse, mutect2, varscan2
- OR2A2 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as rs187987538; called by muse, mutect2, varscan2
- OR51S1 | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV100437490; called by muse, mutect2, varscan2
- OR52H1 | c.400T>A p.Y134N (on ENST00000322653; = p.Y140N on NM_001005289.1) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497332; called by muse, varscan2
- PCDHAC1 | c.2380T>A p.S794T | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.247); catalogued as COSV99166519; called by muse, mutect2, varscan2
- POLDIP2 | c.694G>T p.D232Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV50228874; called by muse, mutect2
- RGS7BP | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV61837885; called by muse, mutect2, varscan2
- SH2D1B | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs189321084; called by muse, mutect2, varscan2
- SIGLEC10 | c.688G>A p.V230I | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.044); catalogued as rs557047713, COSV59480178; called by muse, mutect2
- SKIV2L | c.3703C>T p.R1235W | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1299713670, COSV100514691; called by muse, mutect2
- SLC2A1 | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs138139624; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SORCS1 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.06); catalogued as rs762709776, COSV53877057; called by muse, mutect2, varscan2
- SVEP1 | c.4405A>G p.I1469V | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.017); catalogued as rs946178763, COSV100238067; called by muse, mutect2, varscan2
- SYNE1 | c.4785T>A p.H1595Q (on ENST00000367255 / NM_182961.4; = p.H1602Q on NM_033071.3) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV99565458; called by muse, varscan2
- TMEM50A | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1007138191, COSV100975926; called by muse, mutect2, varscan2
- DLEC1 | c.3711G>A p.A1237= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs377488944; called by muse, mutect2, varscan2
- OR51A7 | c.217C>T p.L73= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs756314063, COSV100834674, COSV63788173; called by muse, mutect2, varscan2
- DNA2 | c.-64C>T | 5'UTR (SNP) | VAF 8/35 reads (23%) | catalogued as rs907852799, COSV100622594; called by muse, mutect2
